Somatic mutation profile of tumor specimen c8694e31-2c8f-4eb6-a7ef-a137d9 (aliquot c8694e31-2c8f-4eb6-a7ef-a137d9_D6_1) from CPTAC case 11CO070, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen c8694e31-2c8f-4eb6-a7ef-a137d9: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a093cc23-dab1-4139-87a9-a416e0c58e08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen e465b51d-3c58-4d02-8552-7f5cd3 (Blood Derived Normal), aliquot e465b51d-3c58-4d02-8552-7f5cd3_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49733dbf-4450-4790-a8fc-5245a6650379

The open-access MAF lists 11,685 somatic variants for this specimen: 8,125 protein-altering or splice-affecting, 2,172 silent, 1,388 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7,218, Silent 2,172, Intron 712, Nonsense Mutation 659, RNA 225, 3'UTR 221, Splice Site 100, Splice Region 98, 5'UTR 96, 5'Flank 91, 3'Flank 41, Frame Shift Ins 21.

Variants (750 of 11,685; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.6118C>T p.R2040* | Nonsense Mutation (SNP) | VAF 35/264 reads (13%) | catalogued as rs61753038, CM032170, COSV64674774; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ALMS1 | c.8005C>T p.R2669* | Nonsense Mutation (SNP) | VAF 43/357 reads (12%) | catalogued as rs549857076, CM050170, COSV52503066; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 78/388 reads (20%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- BCL6 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 59/279 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV51649761; called by muse, mutect2, varscan2
- CFTR | c.2126G>A p.R709Q | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs397508342, CM024683, COSV50043054; ClinVar: likely pathogenic; called by muse, varscan2
- CYP4V2 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 48/333 reads (14%) | catalogued as rs369063468, CM130750; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DHCR24 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 156/648 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs119475041, CM014564; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DSP | c.3316G>T p.E1106* | Nonsense Mutation (SNP) | VAF 68/198 reads (34%) | catalogued as rs1131691673, COSV65791931; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- F5 | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 164/478 reads (34%) | catalogued as rs757953549, CM980661, COSV100888970; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- F8 | c.6544C>T p.R2182C | Missense Mutation (SNP) | VAF 98/222 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852467, CM002001, CM061754, COSV57704780; ClinVar: pathogenic; called by muse, varscan2
- F8 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137852404, CM930213, COSV64270281; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR1 | c.443G>A p.R148H (on ENST00000447712 / NM_023110.3; = p.X148_splice on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/365 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as rs515726222, CM167100, COSV58334916; ClinVar: pathogenic / uncertain significance; called by muse, varscan2
- FOXP1 | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 126/570 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs763413735, COSV59534728; called by muse, mutect2, varscan2
- GLB1 | c.396+2T>C p.X132_splice | Splice Site (SNP) | VAF 100/400 reads (25%) | catalogued as rs1057517738; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAQ | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 31/175 reads (18%) | hotspot (GDC flag); catalogued as COSV54106777, COSV99680195; called by muse, mutect2, varscan2
- GNPTAB | c.1759C>T p.R587* | Nonsense Mutation (SNP) | VAF 24/194 reads (12%) | catalogued as rs281864982, CM100341, COSV54779098, COSV68449787; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KAT6A | c.3505C>T p.R1169* | Nonsense Mutation (SNP) | VAF 15/199 reads (8%) | catalogued as rs886042000; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- KMT2D | c.7933C>T p.R2645* | Nonsense Mutation (SNP) | VAF 56/301 reads (19%) | catalogued as rs1555191740, CM111915, COSV56409935; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 54/293 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRIT1 | c.1849G>T p.E617* | Nonsense Mutation (SNP) | VAF 19/274 reads (7%) | catalogued as rs1554503116, CM034215; ClinVar: pathogenic; called by muse, mutect2
- LAMA2 | c.1300C>T p.R434* | Nonsense Mutation (SNP) | VAF 43/212 reads (20%) | catalogued as rs1374568851; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAP2K4 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 46/179 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV62255770, COSV62259440; called by muse, mutect2, varscan2
- MSH6 | c.3964G>T p.E1322* | Nonsense Mutation (SNP) | VAF 59/209 reads (28%) | catalogued as rs1553333707, CM1412053, COSV52274101; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.5533C>T p.R1845W | Missense Mutation (SNP) | VAF 60/510 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28933098, CM032961, COSV62517164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 190/770 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs730880870, CM066922, COSV62518906; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- NALCN | c.2563C>T p.R855* | Nonsense Mutation (SNP) | VAF 46/212 reads (22%) | catalogued as rs376152742; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.5044C>T p.R1682* | Nonsense Mutation (SNP) | VAF 21/144 reads (15%) | catalogued as rs797045769, COSV56944290; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PAX6 | c.164A>C p.K55T | Missense Mutation (SNP) | VAF 113/399 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1131692294, CM078152; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PBRM1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 67/196 reads (34%) | hotspot (GDC flag); catalogued as COSV56260264, COSV56262552; called by muse, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 32/112 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 49/147 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); catalogued as COSV55885255, COSV55891864; called by muse, mutect2
- PIK3CA | c.1634A>G p.E545G | Missense Mutation (SNP) | VAF 18/58 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 84/252 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RTKN2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | hotspot (GDC flag); catalogued as rs772033296, COSV65679700, COSV65679972; called by muse, mutect2, varscan2
- RYR2 | c.7160C>T p.A2387V | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs794728754, CM133736, COSV100770994; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4573C>T p.R1525* (on ENST00000303395 / NM_001202435.3; = p.R1514* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 35/143 reads (24%) | catalogued as rs794726752, CM065456, COSV57659034, COSV57669725; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC25A13 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 68/285 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1312396424, CM103908, COSV104377556; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TGFBR1 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 90/374 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs111854391, CM061221, COSV66624834; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TMPRSS3 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 217/790 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs137853000, CM054158, CM1513228; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTR | c.88T>C p.C30R | Missense Mutation (SNP) | VAF 86/315 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs121918083, CM920682; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A1BG | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 104/254 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.104); catalogued as COSV99568313; called by muse, mutect2, varscan2
- A2M | c.827C>A p.S276Y | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV59393485; called by muse, mutect2, varscan2
- A2M | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 40/172 reads (23%) | catalogued as COSV59393116; called by mutect2, varscan2
- AARD | c.444A>C p.K148N | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV65600362; called by muse, mutect2, varscan2
- AARS1 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 34/364 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.097); catalogued as rs764124393, COSV55746846; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AARS2 | c.390C>A p.F130L | Missense Mutation (SNP) | VAF 31/375 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55117757; called by muse, mutect2
- AATK | c.757G>A p.D253N (on ENST00000326724 / NM_001080395.3; = p.D150N on NM_004920.2) | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1369774528; called by muse, mutect2
- ABAT | c.286C>A p.L96I | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV51620117; called by muse, varscan2
- ABAT | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 48/361 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748530728; called by muse, mutect2, varscan2
- ABCA10 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149568652; called by muse, mutect2, varscan2
- ABCA12 | c.5849G>A p.R1950Q (on ENST00000272895 / NM_173076.3; = p.R1632Q on NM_015657.3) | Missense Mutation (SNP) | VAF 30/295 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as rs778296113; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA12 | c.4033G>A p.G1345R (on ENST00000272895 / NM_173076.3; = p.G1027R on NM_015657.3) | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745333434, COSV55949543, COSV55974018; called by muse, mutect2, varscan2
- ABCA13 | c.2338A>C p.S780R | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV70026295; called by muse, mutect2, varscan2
- ABCA13 | c.3378A>C p.Q1126H | Missense Mutation (SNP) | VAF 28/366 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV70025734; called by muse, mutect2
- ABCA13 | c.5003G>A p.R1668H | Missense Mutation (SNP) | VAF 64/594 reads (11%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs566240276, COSV70028171; called by mutect2, varscan2
- ABCA13 | c.9397C>T p.P3133S | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs1307532783, COSV71285034; called by muse, mutect2
- ABCA13 | c.12979T>C p.C4327R | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761623940; called by mutect2, varscan2
- ABCA2 | c.217C>T p.R73* (on ENST00000614293; = p.R43* on NM_001606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 64/449 reads (14%) | catalogued as rs767208385; called by muse, mutect2, varscan2
- ABCA3 | c.2512C>T p.R838W | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773021659, COSV100068867; called by mutect2, varscan2
- ABCA5 | c.4843G>T p.E1615* | Nonsense Mutation (SNP) | VAF 11/104 reads (11%) | catalogued as COSV52228263; called by muse, mutect2, varscan2
- ABCA5 | c.3144+1G>A p.X1048_splice | Splice Site (SNP) | VAF 10/54 reads (19%) | catalogued as rs149728283; called by mutect2, varscan2
- ABCA6 | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.119); catalogued as rs776811252, COSV104371218, COSV52638515; called by muse, mutect2, varscan2
- ABCA8 | c.3013G>T p.D1005Y | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV52203515; called by muse, mutect2, varscan2
- ABCB11 | c.972C>A p.F324L | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.014); catalogued as rs1192578960, COSV55588431; called by muse, mutect2, varscan2
- ABCB5 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 58/262 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs368226947; called by muse, mutect2, varscan2
- ABCB6 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 53/334 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772815355, COSV54693434; called by muse, mutect2, varscan2
- ABCB7 | c.2252C>T p.S751L (on ENST00000373394 / NM_001271696.3; = p.S752L on NM_004299.6) | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs372891558, COSV53717978; called by muse, mutect2, varscan2
- ABCC2 | c.3310A>G p.T1104A | Missense Mutation (SNP) | VAF 89/381 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1378999451; called by muse, mutect2, varscan2
- ABCC5 | c.2041C>T p.R681* | Nonsense Mutation (SNP) | VAF 15/254 reads (6%) | catalogued as COSV55592077; called by muse, mutect2
- ABCC5 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs758646463, COSV55586863; called by muse, mutect2, varscan2
- ABCC9 | c.3338C>A p.S1113Y | Missense Mutation (SNP) | VAF 70/336 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.516); catalogued as COSV99687197; called by mutect2, varscan2
- ABCC9 | c.2648T>C p.I883T | Missense Mutation (SNP) | VAF 35/311 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751892751; called by muse, mutect2, varscan2
- ABCC9 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs746967404, COSV53962075, COSV53967382; called by muse, mutect2, varscan2
- ABCC9 | c.349A>G p.T117A | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.129); catalogued as rs1407766562; called by muse, mutect2
- ABCF1 | c.779A>C p.K260T | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV100400658; called by muse, mutect2
- ABCG1 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT tolerated (0.97); PolyPhen benign (0.182); catalogued as rs1184783690; called by muse, mutect2, varscan2
- ABCG2 | c.1346T>C p.V449A | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.271); catalogued as rs767101087; called by muse, mutect2, varscan2
- ABL2 | c.445C>T p.R149C (on ENST00000502732 / NM_007314.4; = p.R134C on NM_005158.5) | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs375837168; called by muse, mutect2, varscan2
- ABRAXAS1 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.816); catalogued as COSV58948112, COSV58950163; called by muse, mutect2, varscan2
- ABT1 | c.695A>G p.E232G | Missense Mutation (SNP) | VAF 67/312 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs1300147418, COSV51290959; called by mutect2, varscan2
- AC010255.2 | c.152A>C p.K51T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1319404984; called by muse, mutect2, varscan2
- AC010973.3 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 76/299 reads (25%) | catalogued as rs779854635, COSV52530212; called by muse, mutect2, varscan2
- AC011462.1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 52/554 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs762665826, COSV54199224; called by muse, mutect2
- AC114490.3 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1557549759; called by muse, varscan2
- ACACB | c.3154C>T p.R1052C | Missense Mutation (SNP) | VAF 101/321 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as rs777435824, COSV100623248; called by muse, mutect2, varscan2
- ACACB | c.3673C>T p.R1225W | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs759403747, COSV100622529; called by muse, mutect2, varscan2
- ACAD10 | c.1250A>G p.Y417C | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748687718; called by muse, mutect2, varscan2
- ACADM | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs769906625, COSV63720304; called by muse, mutect2, varscan2
- ACAP1 | c.1333G>A p.G445S | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376167360; called by muse, mutect2, varscan2
- ACBD3 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766741908, COSV64729849; called by muse, mutect2, varscan2
- ACBD3 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 35/310 reads (11%) | catalogued as rs781141478, COSV64730313; called by muse, mutect2, varscan2
- ACBD5 | c.1204G>A p.E402K (on ENST00000375888 / NM_001352568.1; = p.E393K on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.167); catalogued as rs777230785, COSV65519169; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACBD5 | c.910G>A p.D304N (on ENST00000375888 / NM_001352568.1; = p.D295N on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs746449573; called by muse, mutect2, varscan2
- ACHE | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 37/420 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs768377541, COSV99574289; called by muse, mutect2
- ACIN1 | c.3952C>T p.R1318C | Missense Mutation (SNP) | VAF 48/367 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs754538392, COSV52973736; called by muse, mutect2, varscan2
- ACIN1 | c.2020C>T p.P674S | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.986); catalogued as rs1051301044; called by muse, mutect2, varscan2
- ACMSD | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267598885, COSV51606002, COSV51609903; called by muse, varscan2
- ACOT11 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765531015, COSV59347289; called by muse, mutect2, varscan2
- ACOT11 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs750295708, COSV100989447; called by mutect2, varscan2
- ACOX3 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs762558027, COSV62711619; called by muse, mutect2, varscan2
- ACP1 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs772626530, COSV55242773; called by mutect2, varscan2
- ACP3 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 23/109 reads (21%) | catalogued as rs758538660, COSV60485862; called by muse, mutect2, varscan2
- ACP4 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 60/359 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as rs115449310; called by muse, mutect2, varscan2
- ACSL1 | c.1735C>T p.R579* | Nonsense Mutation (SNP) | VAF 32/169 reads (19%) | catalogued as rs1160032491, COSV55662898; called by muse, mutect2, varscan2
- ACSL1 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs774034663; called by mutect2, varscan2
- ACSM1 | c.1116G>A p.T372= | Splice Region (SNP) | VAF 15/87 reads (17%) | catalogued as rs765295558, COSV54633186; called by muse, mutect2, varscan2
- ACSM3 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99184668; called by muse, mutect2, varscan2
- ACSM3 | c.305C>A p.S102Y | Missense Mutation (SNP) | VAF 55/319 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV55501173, COSV55504773; called by muse, mutect2, varscan2
- ACSM6 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 58/231 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs778886954, COSV58978473, COSV58979152; called by muse, mutect2, varscan2
- ACTR10 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as rs554639681, COSV54298006; called by muse, mutect2, varscan2
- ACVR1C | c.91C>A p.L31I | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.21); catalogued as COSV54645242; called by muse, mutect2, varscan2
- ACY3 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 43/496 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as COSV54829709; called by muse, mutect2
- ACYP1 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs113807807, COSV99465206; called by muse, mutect2, varscan2
- ADAD1 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs770989160, COSV56641414; called by muse, mutect2, varscan2
- ADAD1 | c.1703C>A p.S568Y | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as COSV99635698; called by muse, mutect2, varscan2
- ADAD2 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.013); catalogued as rs754711184; called by mutect2, varscan2
- ADAM11 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 73/288 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as rs376893849; called by muse, mutect2, varscan2
- ADAM15 | c.1972C>T p.R658* | Nonsense Mutation (SNP) | VAF 25/129 reads (19%) | catalogued as rs755490535, COSV55125843; called by muse, mutect2, varscan2
- ADAM19 | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.076); catalogued as rs1229955511; called by muse, mutect2, varscan2
- ADAM20 | c.1294G>T p.D432Y | Missense Mutation (SNP) | VAF 41/408 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56456734; called by muse, mutect2, varscan2
- ADAM30 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 49/428 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs755709661, COSV65561671; called by muse, mutect2, varscan2
- ADAM33 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1481654912; called by muse, varscan2
- ADAM33 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as COSV100597856; called by muse, varscan2
- ADAM9 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.506); catalogued as rs1344174952, COSV65946589; called by muse, mutect2, varscan2
- ADAMTS1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 102/670 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1447879270; called by muse, varscan2
- ADAMTS10 | c.1304C>A p.S435Y | Missense Mutation (SNP) | VAF 30/714 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54355156; called by muse, mutect2
- ADAMTS12 | c.4762C>A p.L1588I | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV61255253; called by muse, mutect2, varscan2
- ADAMTS12 | c.4262C>T p.P1421L | Missense Mutation (SNP) | VAF 63/260 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs758679740, COSV61266694; called by muse, mutect2, varscan2
- ADAMTS12 | c.3707T>G p.V1236G | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV61279610; called by muse, mutect2, varscan2
- ADAMTS13 | c.3658C>T p.P1220S | Missense Mutation (SNP) | VAF 94/643 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52471359; called by muse, mutect2, varscan2
- ADAMTS16 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs762198703, COSV56985669; called by muse, mutect2, varscan2
- ADAMTS18 | c.2498C>T p.A833V | Missense Mutation (SNP) | VAF 57/402 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs147816593; called by muse, mutect2, varscan2
- ADAMTS19 | c.3555G>T p.K1185N | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.913); catalogued as COSV50805247; called by muse, mutect2
- ADAMTS2 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 125/526 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755997172, COSV51072403; called by muse, mutect2, varscan2
- ADAMTS20 | c.993G>T p.K331N | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs370008149, COSV67130141; called by muse, mutect2, varscan2
- ADAMTS5 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1286298815, COSV53175922; called by muse, mutect2, varscan2
- ADAMTS6 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs778280146, COSV66858507; called by mutect2, varscan2
- ADAMTS9 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs373729997; called by muse, mutect2, varscan2
- ADAMTSL1 | c.74C>T p.T25I | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs756911048; called by mutect2, varscan2
- ADAMTSL2 | c.263G>T p.R88M | Missense Mutation (SNP) | VAF 39/483 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV63203761; called by muse, mutect2
- ADAMTSL3 | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54443016, COSV99720411; called by muse, mutect2, varscan2
- ADAMTSL4 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 62/381 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs587699176, COSV55002018; called by muse, mutect2, varscan2
- ADCK2 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 61/235 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs745347858, COSV99301295; called by muse, mutect2, varscan2
- ADCY10 | c.4345C>A p.L1449I | Missense Mutation (SNP) | VAF 107/379 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs749690491, COSV63239583, COSV63240944, COSV63245296; called by muse, mutect2, varscan2
- ADCY4 | c.2297C>T p.S766L | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as COSV60253633; called by muse, mutect2
- ADD2 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781842295, COSV52458987; called by muse, mutect2, varscan2
- ADGB | c.2224C>T p.R742C | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs369635691, COSV104400852; called by muse, mutect2, varscan2
- ADGB | c.2651C>A p.S884Y | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV62223656; called by muse, mutect2
- ADGB | c.3005C>A p.S1002Y | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as rs966111017, COSV62221889; called by muse, mutect2
- ADGB | c.3565C>A p.L1189I | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.027); catalogued as rs925757431; called by muse, mutect2, varscan2
- ADGRB1 | c.3016C>T p.R1006C | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs1282627260; called by muse, varscan2
- ADGRD1 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1296156870, COSV55439564; called by muse, mutect2, varscan2
- ADGRF1 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 50/327 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143178573, COSV51947538; called by muse, mutect2, varscan2
- ADGRF5 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 91/370 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.83); catalogued as rs767381721, COSV51929845; called by muse, mutect2, varscan2
- ADGRG1 | c.906G>T p.K302N | Missense Mutation (SNP) | VAF 134/462 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as COSV65635573; called by muse, varscan2
- ADGRG3 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs956876949; called by muse, mutect2, varscan2
- ADGRG4 | c.2395T>G p.F799V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54952951; called by muse, mutect2, varscan2
- ADGRG5 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758492374, COSV61082714; called by muse, mutect2, varscan2
- ADGRG6 | c.1217G>T p.R406M | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV51600896, COSV51601845; called by muse, mutect2
- ADGRL2 | c.1011G>T p.K337N | Missense Mutation (SNP) | VAF 40/516 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.263); catalogued as COSV54680639; called by muse, mutect2
- ADGRL2 | c.1400G>T p.R467I | Missense Mutation (SNP) | VAF 32/337 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.1); catalogued as COSV54655136, COSV54656571; called by muse, mutect2
- ADGRV1 | c.9094C>A p.L3032I | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.033); catalogued as COSV67978992, COSV67980365; called by muse, mutect2
- ADGRV1 | c.10601C>T p.S3534L | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs778374104, COSV67982263; called by muse, varscan2
- ADGRV1 | c.11956G>T p.E3986* | Nonsense Mutation (SNP) | VAF 9/107 reads (8%) | catalogued as COSV67987903; called by muse, mutect2
- ADGRV1 | c.18347C>T p.S6116F | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV101316501, COSV67988003; called by muse, mutect2, varscan2
- ADIPOR2 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777599853, COSV63947216; called by muse, mutect2, varscan2
- ADORA1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 48/370 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs146812291; called by muse, varscan2
- ADORA1 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58809929, COSV58813432; called by muse, mutect2, varscan2
- ADORA1 | c.752A>G p.H251R | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs775034018; called by muse, mutect2, varscan2
- ADRA1B | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 65/575 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60701808; called by muse, mutect2, varscan2
- ADRA2A | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746155867, COSV54530057; called by muse, mutect2
- ADRA2B | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 73/505 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV101337397; called by muse, mutect2, varscan2
- ADRA2C | c.455C>A p.S152* | Nonsense Mutation (SNP) | VAF 67/423 reads (16%) | catalogued as COSV57467182; called by muse, mutect2, varscan2
- AEBP1 | c.2359G>A p.A787T | Missense Mutation (SNP) | VAF 100/388 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as rs759775732; called by muse, mutect2, varscan2
- AFF1 | c.817A>G p.T273A | Missense Mutation (SNP) | VAF 33/362 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as rs752052622; called by muse, mutect2
- AFF1 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 37/305 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.912); catalogued as rs756223669; called by muse, mutect2, varscan2
- AFF3 | c.2987A>G p.E996G | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100418692; called by muse, mutect2, varscan2
- AFG3L1P | n.700+6G>T | Splice Region (SNP) | VAF 18/116 reads (16%) | catalogued as rs955349949; called by muse, mutect2, varscan2
- AFM | c.1346C>A p.S449Y | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs1443505725; called by muse, mutect2, varscan2
- AGAP1 | c.2212C>T p.R738W (on ENST00000304032 / NM_001037131.3; = p.R685W on NM_014914.5) | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs766842363; called by muse, mutect2, varscan2
- AGL | c.1130G>T p.R377I | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV54051702; called by muse, mutect2, varscan2
- AGMO | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377383575; called by muse, mutect2, varscan2
- AGO3 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs1466158162, COSV55791614; called by muse, mutect2, varscan2
- AGT | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 88/1228 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs138660113; called by muse, mutect2
- AGTPBP1 | c.2357C>T p.S786L (on ENST00000357081 / NM_001330701.2; = p.S746L on NM_015239.2) | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1301788639, COSV61270146; called by muse, mutect2, varscan2
- AGTR1 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 95/300 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200184769, COSV62557211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGXT2 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs200627716; called by muse, mutect2, varscan2
- AGXT2 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1163066610, COSV51486036; called by muse, mutect2, varscan2
- AHI1 | c.3410C>A p.S1137Y | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.055); catalogued as COSV99662163; called by muse, mutect2, varscan2
- AHNAK2 | c.16450A>G p.T5484A | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.495); catalogued as rs1162510591; called by muse, mutect2
- AHNAK2 | c.11632G>A p.E3878K | Missense Mutation (SNP) | VAF 82/519 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as rs756284833; called by muse, mutect2, varscan2
- AIM2 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 47/131 reads (36%) | catalogued as rs145420527; called by muse, mutect2, varscan2
- AIM2 | c.10A>C p.K4Q | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV100931073; called by muse, mutect2, varscan2
- AIMP1 | c.518C>A p.S173Y | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs143219988; called by muse, varscan2
- AIPL1 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 94/372 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs763298873; called by muse, mutect2, varscan2
- AK5 | c.1008G>T p.M336I (on ENST00000354567 / NM_174858.3; = p.M310I on NM_012093.4) | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100643344; called by muse, mutect2, varscan2
- AK5 | c.1620+2C>T p.X540_splice (on ENST00000354567 / NM_174858.3; = p.X514_splice on NM_012093.4) | Splice Site (SNP) | VAF 13/67 reads (19%) | catalogued as rs770347979, COSV100642358; called by muse, mutect2, varscan2
- AK9 | c.4177T>G p.F1393V | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101440505; called by muse, mutect2, varscan2
- AKAP1 | c.995A>G p.D332G | Missense Mutation (SNP) | VAF 42/308 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as rs867754705; called by muse, mutect2, varscan2
- AKAP11 | c.3725C>T p.S1242L | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs373903269; called by muse, mutect2, varscan2
- AKAP12 | c.4081G>A p.E1361K | Missense Mutation (SNP) | VAF 33/296 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751095666, COSV53574731; called by muse, mutect2, varscan2
- AKAP13 | c.2929G>T p.A977S | Missense Mutation (SNP) | VAF 36/379 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as COSV63464018; called by muse, mutect2
- AKAP3 | c.1542G>T p.E514D | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs749128877, COSV57420287; called by mutect2, varscan2
- AKAP3 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs545087055, COSV57414658, COSV57420537; called by muse, mutect2, varscan2
- AKAP6 | c.3325G>T p.E1109* | Nonsense Mutation (SNP) | VAF 46/274 reads (17%) | catalogued as COSV55212455; called by muse, varscan2
- AKR1B1 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 44/427 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.073); catalogued as rs765362829; called by muse, mutect2, varscan2
- AKR1B15 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs373511828; called by muse, mutect2, varscan2
- AKR7L | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs112624478; called by muse, mutect2, varscan2
- AL592490.1 | c.2648C>A p.S883Y | Missense Mutation (SNP) | VAF 63/559 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.172); catalogued as COSV69426126; called by muse, mutect2, varscan2
- AL645922.1 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 42/498 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.391); catalogued as rs1262802568, COSV104408319; called by muse, mutect2
- AL645922.1 | c.2114G>A p.R705Q | Missense Mutation (SNP) | VAF 87/651 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745794224, CM103422, COSV54960081; called by muse, mutect2, varscan2
- AL713999.2 | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 17/149 reads (11%) | catalogued as COSV55280762; called by muse, mutect2, varscan2
- ALB | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.792); catalogued as COSV55743377; called by muse, mutect2
- ALB | c.1194C>T p.F398= | Splice Region (SNP) | VAF 57/231 reads (25%) | catalogued as rs770952660, COSV55735522, COSV55737469; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH3A1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.577); catalogued as rs750383473, COSV56736817; called by muse, mutect2, varscan2
- ALDH3B1 | c.948C>T p.I316= | Splice Region (SNP) | VAF 26/222 reads (12%) | catalogued as rs532748788, COSV99141931; called by muse, mutect2, varscan2
- ALDH3B2 | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 83/419 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV62427630; called by muse, mutect2, varscan2
- ALG10 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as rs769926406, COSV99848404; called by muse, varscan2
- ALG6 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.138); catalogued as COSV54766239; called by muse, mutect2, varscan2
- ALK | c.4523G>T p.G1508V | Missense Mutation (SNP) | VAF 50/532 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66578701; called by muse, mutect2
- ALK | c.3358C>T p.R1120W | Missense Mutation (SNP) | VAF 162/677 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774951734, COSV66580669; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALK | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1272214012; ClinVar: uncertain significance; called by muse, mutect2
- ALKBH7 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755922067, COSV55532649, COSV55532815; called by mutect2, varscan2
- ALOX5AP | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs760124781; called by muse, varscan2
- ALOXE3 | c.1714G>T p.E572* | Nonsense Mutation (SNP) | VAF 54/441 reads (12%) | catalogued as COSV59073935; called by muse, mutect2, varscan2
- ALPI | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 42/296 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55016396; called by muse, varscan2
- ALS2CL | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs761173942, COSV59672940; called by muse, mutect2, varscan2
- AMACR | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 36/415 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs774406448, COSV56869837; called by muse, mutect2
- AMBN | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV59827212; called by muse, mutect2, varscan2
- AMBN | c.1326G>A p.W442* | Nonsense Mutation (SNP) | VAF 40/156 reads (26%) | catalogued as rs1297758923; called by muse, varscan2
- AMBP | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs199571996, COSV99468886; called by muse, mutect2, varscan2
- AMFR | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs1393940024, COSV51922153; called by muse, mutect2
- AMMECR1 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53320478; called by muse, mutect2, varscan2
- AMOTL1 | c.2161C>T p.R721W | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs776691984, COSV100504316; called by muse, mutect2, varscan2
- AMOTL1 | c.2766G>T p.E922D | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs775836171; called by muse, mutect2, varscan2
- AMOTL2 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 62/798 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs751105132, COSV51441113; called by muse, mutect2
- AMPD1 | c.1110G>T p.K370N | Missense Mutation (SNP) | VAF 100/388 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as rs750474668; called by muse, mutect2, varscan2
- AMPH | c.1135A>G p.T379A | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV57733127, COSV57755178; called by muse, varscan2
- AMTN | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs753945509, COSV100219867; called by muse, mutect2, varscan2
- ANAPC5 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV99945964; called by muse, mutect2, varscan2
- ANAPC5 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.353); catalogued as COSV55842418; called by muse, mutect2, varscan2
- ANAPC7 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1351434158; called by muse, varscan2
- ANGPT4 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs773004657, COSV67920540; called by muse, mutect2, varscan2
- ANGPTL6 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as rs1055750184; called by muse, mutect2, varscan2
- ANK2 | c.2375C>T p.A792V | Missense Mutation (SNP) | VAF 41/413 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0.056); catalogued as COSV52180556; called by muse, varscan2
- ANK3 | c.6121A>G p.I2041V | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as rs797045236; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKAR | c.3913C>T p.R1305C | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs542000323, COSV51461960; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3401G>A p.R1134H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.91); catalogued as rs770042343; called by mutect2, varscan2
- ANKMY1 | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs773858255; called by muse, mutect2, varscan2
- ANKRD12 | c.2252G>A p.R751Q | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs768252877; called by mutect2, varscan2
- ANKRD13B | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 58/239 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs1185601751; called by muse, mutect2, varscan2
- ANKRD18B | c.1931T>G p.F644C | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.766); catalogued as COSV52086212; called by muse, mutect2, varscan2
- ANKRD23 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV58412819; called by muse, mutect2, varscan2
- ANKRD26 | c.3439C>T p.R1147* | Nonsense Mutation (SNP) | VAF 34/117 reads (29%) | catalogued as rs151033255, COSV65774138; called by muse, mutect2, varscan2
- ANKRD27 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555830097, COSV60129915; called by muse, mutect2, varscan2
- ANKRD30A | c.1459C>A p.L487I (on ENST00000611781; = p.L431I on NM_052997.2) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.82); PolyPhen benign (0.341); catalogued as COSV64624147; called by muse, mutect2, varscan2
- ANKRD30A | c.3229G>T p.D1077Y (on ENST00000611781; = p.D1021Y on NM_052997.2) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100654526, COSV64604435; called by mutect2, varscan2
- ANKRD30B | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as rs1468982864, COSV62810723; called by muse, mutect2, varscan2
- ANKRD30B | c.2977G>T p.E993* | Nonsense Mutation (SNP) | VAF 12/108 reads (11%) | catalogued as rs1293354384, COSV100271633; called by muse, mutect2, varscan2
- ANKRD33 | c.224G>A p.R75Q (on ENST00000340970 / NM_001304459.2; = p.R210Q on NM_182608.4) | Missense Mutation (SNP) | VAF 47/293 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as rs199622035; called by muse, mutect2, varscan2
- ANKRD36 | c.847G>T p.D283Y | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757138047, COSV101347535; called by muse, varscan2
- ANKRD36 | c.2128G>T p.E710* | Nonsense Mutation (SNP) | VAF 22/130 reads (17%) | catalogued as COSV70740916; called by muse, varscan2
- ANKRD36C | c.2797G>A p.E933K | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.118); catalogued as rs1322830475, COSV54766386; called by muse, mutect2
- ANKRD36C | c.2365C>A p.P789T | Missense Mutation (SNP) | VAF 73/325 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV54766351; called by muse, mutect2, varscan2
- ANKRD44 | c.2851C>T p.R951C | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760008651, COSV56552307; called by muse, mutect2, varscan2
- ANKRD50 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs368512857; called by muse, mutect2, varscan2
- ANKS1A | c.1115C>A p.S372* | Nonsense Mutation (SNP) | VAF 31/146 reads (21%) | catalogued as COSV64463138; called by muse, mutect2, varscan2
- ANKS1B | c.3391C>T p.R1131C (on ENST00000547776 / NM_152788.4; = p.R297C on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs965673606, COSV59124585; called by muse, mutect2, varscan2
- ANKS1B | c.2735C>T p.S912L (on ENST00000547776 / NM_152788.4; = p.S138L on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60357807; called by muse, mutect2
- ANKS1B | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as rs571014607, COSV61358870; called by muse, mutect2, varscan2
- ANKS6 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 44/431 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747073459, COSV62050205, COSV62052560; called by muse, mutect2, varscan2
- ANKZF1 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 37/312 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750431702, COSV55476317; called by muse, mutect2, varscan2
- ANO2 | c.851G>A p.R284H (on ENST00000356134 / NM_001278597.3; = p.R288H on NM_001278596.3) | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs368783366, COSV59046108; called by muse, varscan2
- ANO3 | c.2657+2T>C p.X886_splice | Splice Site (SNP) | VAF 10/85 reads (12%) | catalogued as rs1371459445; called by muse, mutect2, varscan2
- ANO4 | c.628C>T p.R210W (on ENST00000392977 / NM_001286615.2; = p.R175W on NM_178826.4) | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.719); catalogued as rs372521580; called by muse, mutect2, varscan2
- ANO4 | c.950G>A p.R317Q (on ENST00000392977 / NM_001286615.2; = p.R282Q on NM_178826.4) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1202630749, COSV54594794; called by muse, mutect2, varscan2
- ANO7 | c.348G>T p.W116C (on ENST00000274979; = p.W61C on NM_001001666.4) | Missense Mutation (SNP) | VAF 90/387 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51470098; called by muse, varscan2
- ANP32E | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as rs1553841780; called by muse, mutect2
- ANTXR1 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774300710, COSV58013918; called by muse, varscan2
- ANXA9 | c.472+1G>A p.X158_splice | Splice Site (SNP) | VAF 18/169 reads (11%) | catalogued as rs778582095, COSV100929061; called by mutect2, varscan2
- ANXA9 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 71/359 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as rs150067239; called by muse, mutect2, varscan2
- AOC3 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 137/561 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs766793528, COSV53828577; called by muse, mutect2, varscan2
- AOC3 | c.2017G>A p.D673N | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1265519481; called by muse, mutect2
- AP000812.4 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1262779917; called by muse, mutect2, varscan2
- AP002748.5 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 86/596 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs770668729; called by muse, mutect2, varscan2
- AP1B1 | c.2038G>A p.V680M | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs759149457; called by muse, mutect2, varscan2
- AP1G1 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 76/297 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV55492956; called by muse, mutect2, varscan2
- AP3B1 | c.1787A>G p.K596R | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV54893896; called by muse, mutect2, varscan2
- AP3B1 | c.128+8G>A | Splice Region (SNP) | VAF 50/335 reads (15%) | catalogued as COSV54876216; called by muse, mutect2, varscan2
- AP3B2 | c.1960C>T p.R654C | Missense Mutation (SNP) | VAF 64/413 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs760853121, COSV55606048; called by muse, mutect2, varscan2
- AP3B2 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442353474, COSV55608425; called by muse, mutect2, varscan2
- AP3B2 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as COSV55608049; called by muse, mutect2, varscan2
- AP3M2 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99441532; called by muse, mutect2, varscan2
- AP5Z1 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1196396832, COSV100804200; called by muse, mutect2
- APBA1 | c.2468C>T p.A823V | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs1476460860; called by muse, varscan2
- APBA1 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs749295663, COSV55222227; called by muse, mutect2, varscan2
- APBA2 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 64/506 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.362); catalogued as rs142481200; called by muse, varscan2
- APBB3 | c.221A>G p.E74G | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1366410542; called by muse, mutect2, varscan2
- APC | c.3299C>A p.S1100Y | Missense Mutation (SNP) | VAF 83/409 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV57326247; called by muse, varscan2
- APC | c.4463T>G p.L1488* | Nonsense Mutation (SNP) | VAF 52/216 reads (24%) | catalogued as CM095526, COSV57322122, COSV57323073, COSV57360736; called by muse, mutect2, varscan2
- APC | c.7531C>T p.L2511F | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.876); catalogued as rs72541815; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APLP1 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as COSV55704896; called by muse, mutect2, varscan2
- APMAP | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 64/518 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.173); catalogued as rs775710141; called by muse, mutect2, varscan2
- APOB | c.13538T>G p.F4513C | Missense Mutation (SNP) | VAF 50/343 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as rs1231966626, COSV51925234; called by muse, mutect2, varscan2
- APOB | c.12660C>A p.F4220L | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99263701; called by muse, mutect2
- APOBEC3F | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs574015835; called by mutect2, varscan2
- APOBEC3G | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.444); catalogued as rs754373002, COSV101349080; called by muse, mutect2, varscan2
- APOBEC3G | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1011553055, COSV68469998; called by muse, mutect2, varscan2
- APOE | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 181/587 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as rs937063425, COSV52986053; called by muse, mutect2, varscan2
- APOF | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 91/394 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752037994, COSV58476429; called by muse, mutect2, varscan2
- APP | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 51/404 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60994141; called by muse, mutect2, varscan2
- APPBP2 | c.1705G>T p.E569* | Nonsense Mutation (SNP) | VAF 17/114 reads (15%) | catalogued as COSV50025950; called by muse, mutect2, varscan2
- AQP12A | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 43/514 reads (8%) | SIFT tolerated (0.98); PolyPhen benign (0.019); catalogued as rs1296800208; called by muse, mutect2
- AQR | c.1007C>A p.S336Y | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs758263003; called by mutect2, varscan2
- AR | c.1832A>C p.N611T | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM960076, COSV65957660; called by muse, mutect2, varscan2
- ARAP2 | c.3416T>C p.V1139A | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58290882; called by muse, mutect2
- ARAP2 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778125188; called by mutect2, varscan2
- ARC | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs1466856033; called by muse, mutect2
- ARF3 | c.219G>T p.K73N | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.912); catalogued as COSV56741390; called by muse, mutect2, varscan2
- ARFGAP2 | c.710G>A p.S237N | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV100125685; called by muse, mutect2
- ARFGEF1 | c.5321G>A p.R1774Q | Missense Mutation (SNP) | VAF 62/291 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1232838320; called by muse, mutect2, varscan2
- ARGFX | c.251C>A p.S84Y | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); catalogued as COSV57681789, COSV57683101; called by muse, mutect2, varscan2
- ARGLU1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.984); catalogued as rs1402870612, COSV62271387; called by muse, mutect2, varscan2
- ARHGAP10 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); catalogued as rs768626844; called by muse, mutect2, varscan2
- ARHGAP15 | c.271A>C p.I91L | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as COSV54528408; called by muse, mutect2, varscan2
- ARHGAP17 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs768561975; called by muse, mutect2, varscan2
- ARHGAP17 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99254037; called by muse, mutect2, varscan2
- ARHGAP19 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as COSV57392369, COSV57392530, COSV57393591; called by muse, mutect2, varscan2
- ARHGAP21 | c.5773A>C p.S1925R | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.182); catalogued as rs758399337; called by muse, mutect2, varscan2
- ARHGAP21 | c.5186C>T p.S1729L | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as rs776145004, COSV57601850; called by muse, mutect2, varscan2
- ARHGAP23 | c.2998G>A p.D1000N | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as rs1398149710; called by muse, mutect2, varscan2
- ARHGAP24 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs866571196; called by muse, mutect2
- ARHGAP24 | c.1495C>T p.R499* (on ENST00000395184 / NM_001025616.3; = p.R406* on NM_031305.3) | Nonsense Mutation (SNP) | VAF 72/686 reads (10%) | catalogued as COSV51987040; called by muse, mutect2
- ARHGAP26 | c.832+1G>A p.X278_splice | Splice Site (SNP) | VAF 20/79 reads (25%) | catalogued as rs1201927791; called by muse, mutect2, varscan2
- ARHGAP30 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 90/449 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV63516492; called by muse, mutect2, varscan2
- ARHGEF10L | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 72/326 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1280116445; called by muse, mutect2, varscan2
- ARHGEF25 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 102/369 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs756197273, COSV54084640; called by muse, mutect2, varscan2
- ARHGEF4 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV58125819; called by muse, mutect2, varscan2
- ARHGEF6 | c.2047G>T p.D683Y | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV51688847; called by muse, mutect2, varscan2
- ARID1B | c.3014C>A p.S1005Y | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as COSV51675331; called by muse, mutect2
- ARID4B | c.3175C>T p.R1059* | Nonsense Mutation (SNP) | VAF 86/243 reads (35%) | catalogued as COSV51599070, COSV51599207; called by muse, mutect2, varscan2
- ARL1 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1429217176, COSV55371054; called by muse, mutect2, varscan2
- ARL11 | c.62A>G p.D21G | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV56291700; called by muse, mutect2, varscan2
- ARL13B | c.308G>T p.R103I | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1025041382; called by muse, mutect2, varscan2
- ARL14 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748999128, COSV57899960, COSV57899982; called by mutect2, varscan2
- ARMC2 | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as rs372522517; called by muse, varscan2
- ARMCX2 | c.1553C>T p.S518F | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.344); catalogued as rs782089774; called by muse, mutect2, varscan2
- ARPP21 | c.1646G>T p.R549I | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV51795406; called by muse, varscan2
- ARRDC3 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 21/104 reads (20%) | catalogued as COSV54364804, COSV54365403; called by muse, mutect2, varscan2
- ARRDC4 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 67/253 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs759457620, COSV51420299; called by muse, mutect2, varscan2
- ARRDC5 | c.59C>T p.S20L (on ENST00000381781; = p.S6L on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/312 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs773823469, COSV104432113; called by muse, mutect2, varscan2
- ARSD | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs750661580, COSV54201298; called by muse, mutect2, varscan2
- ASAH2 | c.109A>G p.T37A | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as COSV61484126; called by mutect2, varscan2
- ASB11 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs764279966, COSV60354998; called by muse, mutect2, varscan2
- ASB2 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.184); catalogued as rs1342370128; called by mutect2, varscan2
- ASB4 | c.477G>T p.L159F | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752392005; called by mutect2, varscan2
- ASCC3 | c.3254A>C p.N1085T | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs201967628; called by muse, mutect2, varscan2
- ASCC3 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs752951712, COSV100225437, COSV61226544; called by mutect2, varscan2
- ASCL1 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.06); catalogued as COSV57152135, COSV99902144; called by muse, mutect2, varscan2
- ASCL4 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.784); catalogued as rs377379976, COSV60817327; called by muse, varscan2
- ASH1L | c.7123C>T p.R2375C (on ENST00000368346 / NM_001366177.2; = p.R2370C on NM_018489.3) | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.386); catalogued as COSV64212393; called by muse, mutect2, varscan2
- ASH1L | c.2963A>C p.K988T | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV64212432; called by muse, mutect2, varscan2
- ASIC4 | c.1176G>T p.E392D (on ENST00000347842 / NM_182847.3; = p.E411D on NM_018674.6) | Missense Mutation (SNP) | VAF 30/360 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.085); catalogued as COSV61733318; called by muse, mutect2
- ASIC5 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 48/220 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs753653000, COSV72232528; called by muse, mutect2, varscan2
- ASMT | c.982G>T p.D328Y (on ENST00000381229; = p.D356Y on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/365 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV101172530; called by muse, mutect2, varscan2
- ASTN1 | c.2557G>A p.G853S | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs866121483, COSV56063542; called by muse, mutect2
- ASXL2 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 27/82 reads (33%) | catalogued as COSV55453991, COSV55459868; called by muse, mutect2, varscan2
- ASXL3 | c.5972C>T p.S1991F | Missense Mutation (SNP) | VAF 27/398 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as rs1279042251; called by muse, mutect2
- ATAD2 | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 17/124 reads (14%) | catalogued as rs1429466956; called by muse, mutect2, varscan2
- ATF3 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs896815259, COSV58377877; called by muse, mutect2
- ATF6 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs772541349; called by mutect2, varscan2
- ATF6B | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as rs1339337800; called by muse, varscan2
- ATF7 | c.692C>T p.S231L (on ENST00000548446 / NM_001366555.2; = p.S220L on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.686); catalogued as rs372435342; called by muse, mutect2, varscan2
- ATF7IP | c.1049A>C p.E350A | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV99662073; called by muse, mutect2, varscan2
- ATG16L2 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as rs369306828; called by muse, mutect2, varscan2
- ATG5 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1158686992, COSV58347908; called by muse, mutect2, varscan2
- ATG9B | c.904A>G p.N302D | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs1452147197; called by muse, mutect2
- ATL1 | c.701A>G p.K234R | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs371579681; called by muse, varscan2
- ATP10A | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 32/304 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV63512994; called by muse, mutect2
- ATP10D | c.266G>T p.R89I | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV56703617, COSV56706850; called by muse, varscan2
- ATP11B | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 24/84 reads (29%) | catalogued as COSV60026901; called by muse, mutect2, varscan2
- ATP11B | c.961T>C p.W321R | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs899952017; called by muse, mutect2, varscan2
- ATP11B | c.2884C>A p.L962I | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.042); catalogued as rs777376374, COSV60029804; called by muse, mutect2, varscan2
- ATP11C | c.3299G>T p.R1100I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1350755139, COSV100558364; called by muse, mutect2, varscan2
- ATP12A | c.1544G>A p.G515D | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370686149; called by muse, mutect2, varscan2
- ATP12A | c.2060A>G p.D687G | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as rs375375813; called by muse, mutect2, varscan2
- ATP13A2 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 180/749 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.046); catalogued as rs774585729, CM098010, COSV58700382; called by muse, mutect2, varscan2
- ATP13A3 | c.3184G>A p.E1062K | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs531855588, COSV55462596; called by mutect2, varscan2
- ATP13A4 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 102/335 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.172); catalogued as rs929598035, COSV55067905; called by muse, varscan2
- ATP13A5 | c.3442G>T p.E1148* | Nonsense Mutation (SNP) | VAF 73/288 reads (25%) | catalogued as COSV53231776; called by muse, mutect2, varscan2
- ATP13A5 | c.2492A>C p.K831T | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs754200171; called by mutect2, varscan2
- ATP1A1 | c.2828C>T p.S943L | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55192266; called by muse, mutect2
- ATP1A4 | c.1847G>A p.G616E | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332980474, COSV63628244, COSV63628270; called by muse, mutect2, varscan2
- ATP1A4 | c.1876C>A p.H626N | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63626045; called by muse, mutect2
- ATP2A3 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 62/808 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs752171448, COSV99988991; called by muse, mutect2
- ATP2B2 | c.1489C>T p.R497C (on ENST00000352432; = p.R463C on NM_001683.5) | Missense Mutation (SNP) | VAF 61/462 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780277141; called by muse, mutect2, varscan2
- ATP2B4 | c.570C>A p.F190L | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.34); catalogued as COSV58176239; called by muse, mutect2, varscan2
- ATP2C1 | c.1699A>C p.K567Q | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV60762166; called by muse, mutect2
- ATP4A | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 35/360 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763936814, COSV52869334; called by muse, mutect2
- ATP4A | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs776771707, COSV52866414, COSV52870617; called by muse, mutect2, varscan2
- ATP5F1B | c.1514A>G p.Q505R | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.142); catalogued as rs768469953; called by mutect2, varscan2
- ATP6V0A2 | c.1690A>C p.T564P | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs750350373; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1198A>G p.I400V | Missense Mutation (SNP) | VAF 57/429 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs781913425; called by muse, varscan2
- ATP6V1C2 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.322); catalogued as rs371007689; called by muse, mutect2, varscan2
- ATP7A | c.4129T>G p.F1377V | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557238988; called by muse, mutect2, varscan2
- ATP8B4 | c.1344C>A p.F448L | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99463360; called by muse, varscan2
- ATP8B4 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs199688981, COSV99464705; called by mutect2, varscan2
- ATR | c.7087C>T p.R2363* | Nonsense Mutation (SNP) | VAF 53/233 reads (23%) | catalogued as rs868378229, COSV63384075, COSV63388511; called by muse, mutect2, varscan2
- ATR | c.4939C>T p.R1647C | Missense Mutation (SNP) | VAF 63/272 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1348702370, COSV63394418; called by muse, mutect2, varscan2
- ATRIP | c.755C>A p.S252Y | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57176887; called by muse, varscan2
- ATRN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758948800, COSV53527986; called by muse, mutect2, varscan2
- ATRN | c.3082C>T p.P1028S | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs1238158195; called by muse, mutect2, varscan2
- ATRX | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV64870074; called by muse, mutect2, varscan2
- ATXN7 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 35/300 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.061); catalogued as rs777248770, COSV99894642; called by muse, mutect2, varscan2
- ATXN7L1 | c.1465C>T p.R489* | Nonsense Mutation (SNP) | VAF 16/91 reads (18%) | catalogued as COSV66299879; called by muse, mutect2, varscan2
- AURKC | c.617T>C p.L206S (on ENST00000302804 / NM_001015878.2; = p.L172S on NM_003160.3) | Missense Mutation (SNP) | VAF 49/479 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57137743; called by muse, mutect2, varscan2
- AVPR1B | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 44/437 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868928134; called by muse, mutect2
- AXIN2 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1244431726, COSV100195707; called by muse, mutect2, varscan2
- B3GALT1 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV59910212; called by muse, mutect2, varscan2
- B3GAT1 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 90/375 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1473343688, COSV56999995; called by muse, mutect2, varscan2
- B4GALNT4 | c.2977G>T p.D993Y | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57325935; called by muse, mutect2
- B4GALT3 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 72/339 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs373721033; called by muse, mutect2, varscan2
- BAAT | c.672C>A p.V224= | Splice Region (SNP) | VAF 36/218 reads (17%) | catalogued as COSV52288153; called by muse, mutect2, varscan2
- BAHCC1 | c.3979C>T p.P1327S | Missense Mutation (SNP) | VAF 53/288 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.233); catalogued as rs1555654989; called by muse, mutect2, varscan2
- BAHD1 | c.1420C>A p.P474T | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1222492013; called by muse, mutect2, varscan2
- BAMBI | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 44/363 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs369743386; called by muse, mutect2, varscan2
- BANK1 | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as rs1213771996, COSV59839801; called by muse, varscan2
- BANP | c.755C>T p.A252V (on ENST00000286122; = p.A221V on NM_017869.4) | Missense Mutation (SNP) | VAF 44/733 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV53736574; called by muse, mutect2
- BATF | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 62/325 reads (19%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.994); catalogued as COSV54376344; called by muse, mutect2, varscan2
- BAZ1A | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.313); catalogued as rs367891887; called by muse, mutect2, varscan2
- BBS10 | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 33/397 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV53881041; called by muse, mutect2
- BBS10 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs553291328, CM111656, COSV99674826; called by muse, mutect2, varscan2
- BBS2 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.476); catalogued as rs150572808; called by muse, mutect2
- BBS5 | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 49/251 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV54754127; called by muse, mutect2, varscan2
- BBS9 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs541526329, COSV54169144; called by mutect2, varscan2
- BBX | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs770138977, COSV57878573; called by muse, varscan2
- BCAT1 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs772512691, COSV104369957; called by muse, mutect2, varscan2
- BCKDHB | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.042); catalogued as rs748693585, COSV57519100; called by muse, varscan2
- BCL7A | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as COSV55846814; called by muse, mutect2, varscan2
- BCL7C | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs760033767, COSV99288557; called by muse, mutect2, varscan2
- BCO1 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 26/320 reads (8%) | catalogued as rs920963812, COSV50734277; called by muse, mutect2
- BCORL1 | c.3640C>T p.R1214C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs776360677, COSV54391706; called by mutect2, varscan2
- BCR | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.488); catalogued as rs1302621798, COSV100006683; called by muse, mutect2, varscan2
- BDKRB1 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 19/124 reads (15%) | catalogued as COSV53706009, COSV53707383; called by muse, mutect2, varscan2
- BDKRB2 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 47/226 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777611379; called by muse, mutect2, varscan2
- BDNF | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 36/609 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs1349681470, COSV59233092, COSV59234846; called by muse, mutect2
- BEAN1 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 33/352 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs560769176, COSV100227965; called by muse, mutect2
- BECN1 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.689); catalogued as rs995636976; called by muse, mutect2, varscan2
- BEND2 | c.453A>C p.E151D | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as rs776351374; called by muse, mutect2, varscan2
- BEX3 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | catalogued as rs770614081, COSV100244344; called by mutect2, varscan2
- BFSP1 | c.1624A>G p.I542V | Missense Mutation (SNP) | VAF 63/468 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs560943929; called by muse, mutect2, varscan2
- BICD2 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 106/467 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as rs372251238; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BID | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.315); catalogued as COSV58006326; called by muse, mutect2, varscan2
- BIRC6 | c.2339G>A p.R780Q | Missense Mutation (SNP) | VAF 50/284 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.477); catalogued as rs760450276; called by muse, mutect2, varscan2
- BIRC6 | c.4424C>G p.T1475S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.968); catalogued as COSV70206308; called by muse, mutect2, varscan2
- BIRC7 | c.175C>A p.L59M | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99416441; called by mutect2, varscan2
- BLM | c.1856T>C p.F619S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV100757401; called by muse, mutect2
- BMP4 | c.1069G>A p.V357M | Missense Mutation (SNP) | VAF 66/815 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1275495197; called by muse, mutect2
- BMPR1A | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 36/285 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs147971049; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMPR2 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as rs1166280962; called by muse, mutect2, varscan2
- BMS1 | c.2881G>T p.D961Y | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65734002; called by muse, varscan2
- BNC1 | c.611T>C p.I204T | Missense Mutation (SNP) | VAF 65/224 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs765671123; called by muse, mutect2, varscan2
- BNC2 | c.2665C>T p.R889C | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs779084645, COSV66175816; called by mutect2, varscan2
- BPI | c.695C>A p.S232Y (on ENST00000262865; = p.S228Y on NM_001725.3) | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs578216988; called by muse, mutect2, varscan2
- BRCA1 | c.5406+1G>T p.X1802_splice | Splice Site (SNP) | VAF 51/429 reads (12%) | catalogued as CS1213356; called by muse, mutect2, varscan2
- BRCA2 | c.8917C>T p.R2973C | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs45469092; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- BRCC3 | c.810G>T p.K270N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57461779; called by muse, mutect2, varscan2
- BRD3 | c.1966T>C p.S656P | Missense Mutation (SNP) | VAF 40/291 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.286); catalogued as COSV57705582; called by muse, mutect2, varscan2
- BRD3 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs1322230565; called by muse, mutect2, varscan2
- BRINP2 | c.422A>C p.K141T | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100838571; called by muse, mutect2
- BRINP3 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 43/419 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1265844653, COSV66514085, COSV66516923; called by muse, mutect2, varscan2
- BRSK1 | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs745808194; called by mutect2, varscan2
- BSN | c.10708G>A p.D3570N | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779949346; called by mutect2, varscan2
- BSND | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 89/350 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs762233340, COSV64870653; called by muse, mutect2, varscan2
- BTAF1 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 24/90 reads (27%) | catalogued as COSV56439125, COSV56439407; called by muse, mutect2, varscan2
- BTAF1 | c.4391G>A p.R1464Q | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs966281593, COSV56429578; called by muse, mutect2
- BTBD9 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 9/77 reads (12%) | catalogued as rs773093124, COSV58429089; called by mutect2, varscan2
- BTN2A2 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 19/428 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as rs1156599160, COSV61859277; called by muse, mutect2
- BTN3A3 | c.628A>G p.M210V | Missense Mutation (SNP) | VAF 55/416 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1271865986; called by muse, mutect2, varscan2
- BVES | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as COSV58947380, COSV58950329; called by muse, mutect2, varscan2
- BZW1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV63349698; called by muse, mutect2, varscan2
- C10orf71 | c.3425C>A p.S1142* | Nonsense Mutation (SNP) | VAF 34/295 reads (12%) | catalogued as COSV60510865; called by muse, mutect2, varscan2
- C11orf49 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs1173505510; called by muse, mutect2
- C11orf87 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 45/397 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV100535876; called by muse, mutect2, varscan2
- C11orf91 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.807); catalogued as rs963493926; called by muse, mutect2, varscan2
- C11orf94 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs753669332; called by muse, mutect2, varscan2
- C12orf50 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1170721797, COSV53893733; called by muse, mutect2, varscan2
- C12orf56 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1273270241; called by muse, mutect2, varscan2
- C14orf39 | c.506T>G p.F169C | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV58783801; called by muse, mutect2, varscan2
- C16orf46 | c.483A>C p.K161N | Missense Mutation (SNP) | VAF 56/384 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144394384; called by muse, mutect2, varscan2
- C16orf71 | c.560G>A p.S187N | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as rs1197452606; called by muse, mutect2, varscan2
- C17orf97 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 52/369 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as rs966859189, COSV100789313; called by muse, mutect2, varscan2
- C1QL2 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1287763778; called by muse, mutect2, varscan2
- C1QL4 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 22/235 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs1413298563; called by muse, mutect2
- C1QTNF3 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as rs759158354, COSV51467791; called by muse, mutect2, varscan2
- C1QTNF4 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 40/277 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56783532; called by muse, mutect2, varscan2
- C1S | c.1124G>A p.S375N | Missense Mutation (SNP) | VAF 141/612 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100196766; called by muse, varscan2
- C1orf109 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs138176961, COSV63656704; called by muse, mutect2, varscan2
- C1orf158 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 83/531 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1211233768, COSV55346261; called by muse, mutect2, varscan2
- C1orf210 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs897432979, COSV70682464; called by muse, mutect2, varscan2
- C2CD2L | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 42/522 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1170302046; called by muse, mutect2
- C2CD5 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV61727203; called by muse, mutect2, varscan2
- C2CD6 | c.1777C>T p.R593* | Nonsense Mutation (SNP) | VAF 18/99 reads (18%) | catalogued as rs748210926, COSV53792214; called by muse, mutect2, varscan2
- C2CD6 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.164); catalogued as rs761495499, COSV53797381; called by muse, mutect2, varscan2
- C2orf16 | c.694A>T p.I232F | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs551674165; called by mutect2, varscan2
- C2orf73 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as rs777890816; called by muse, varscan2
- C2orf76 | c.281G>A p.S94N | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as COSV58346155, COSV58347254; called by muse, mutect2, varscan2
- C2orf78 | c.479C>A p.S160Y | Missense Mutation (SNP) | VAF 55/427 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs762555583; called by muse, mutect2, varscan2
- C4orf54 | c.4103G>A p.R1368Q | Missense Mutation (SNP) | VAF 79/553 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.773); catalogued as rs374701179, COSV72766670; called by muse, mutect2, varscan2
- C4orf54 | c.3820G>A p.E1274K | Missense Mutation (SNP) | VAF 81/585 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1386888150; called by muse, mutect2, varscan2
- C4orf54 | c.2672C>T p.A891V | Missense Mutation (SNP) | VAF 92/477 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV72767048; called by muse, mutect2, varscan2
- C5AR1 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 106/377 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as rs1407617126; called by muse, mutect2, varscan2
- C6orf52 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.381); catalogued as COSV99468478; called by muse, mutect2, varscan2
- C7 | c.2375G>A p.R792Q | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.335); catalogued as rs372359270; called by muse, mutect2, varscan2
- C7orf31 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 116/420 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.663); catalogued as COSV52220234; called by muse, varscan2
- C8A | c.609G>T p.E203D | Missense Mutation (SNP) | VAF 142/677 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs755886616; called by muse, mutect2, varscan2
- C8A | c.1025T>C p.I342T | Missense Mutation (SNP) | VAF 27/394 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as rs1263317056; called by muse, mutect2
- C8orf88 | c.287A>C p.K96T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs996468663; called by muse, mutect2, varscan2
- C9orf131 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 66/425 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs764495713; called by muse, mutect2, varscan2
- CA3 | c.352-8G>T | Splice Region (SNP) | VAF 20/133 reads (15%) | catalogued as COSV53410969; called by muse, mutect2, varscan2
- CAB39L | c.157C>A p.L53M | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV61714991; called by muse, mutect2, varscan2
- CABIN1 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 62/642 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs772632963; called by muse, mutect2
- CACNA1B | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 85/361 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV53150093; called by muse, mutect2, varscan2
- CACNA1B | c.1582G>T p.E528* | Nonsense Mutation (SNP) | VAF 107/368 reads (29%) | catalogued as rs1554741393; called by muse, mutect2, varscan2
- CACNA1C | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.059); catalogued as rs551396698, CM1414710, COSV59736199; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1C | c.2244C>A p.F748L | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100219471; called by muse, mutect2
- CACNA1D | c.6415G>A p.D2139N (on ENST00000350061 / NM_001128840.3; = p.D2159N on NM_000720.4) | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.356); catalogued as rs1461917633; called by muse, mutect2
- CACNA1E | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 68/234 reads (29%) | catalogued as COSV62395163; called by muse, mutect2, varscan2
- CACNA1E | c.2270C>T p.S757L | Missense Mutation (SNP) | VAF 53/491 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs763922481; called by muse, mutect2, varscan2
- CACNA1E | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 26/309 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.041); catalogued as rs1428423503, COSV62397535; called by muse, mutect2
- CACNA1E | c.4781G>A p.R1594H | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436277931, COSV62382452; called by muse, varscan2
- CACNA1E | c.6709G>A p.E2237K (on ENST00000367573 / NM_001205293.3; = p.E2194K on NM_000721.4) | Missense Mutation (SNP) | VAF 40/462 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.165); catalogued as rs375491167; called by muse, mutect2
- CACNA1F | c.4085G>A p.R1362Q | Missense Mutation (SNP) | VAF 113/212 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs375658952, COSV59903088; called by muse, mutect2, varscan2
- CACNA1G | c.5695G>A p.D1899N | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs762521668, COSV61742122; called by muse, mutect2, varscan2
- CACNA1I | c.2248C>T p.R750C | Missense Mutation (SNP) | VAF 35/302 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773178866; called by muse, mutect2, varscan2
- CACNA2D1 | c.1802A>G p.D601G (on ENST00000356253 / NM_001366867.1; = p.D582G on NM_000722.4) | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as COSV100666749; called by muse, mutect2, varscan2
- CACNA2D1 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV62373094; called by muse, mutect2, varscan2
- CACNA2D4 | c.489C>T p.F163= | Splice Region (SNP) | VAF 43/185 reads (23%) | catalogued as COSV54946451; called by muse, mutect2, varscan2
- CACNB4 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 88/330 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.945); catalogued as rs1277708441, COSV52390681; called by muse, varscan2
- CACNG4 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 41/307 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.866); catalogued as rs1313086207, COSV50925303; called by muse, mutect2, varscan2
- CAD | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.207); catalogued as rs775146460, COSV53028693; called by muse, mutect2, varscan2
- CADPS | c.4048G>A p.E1350K | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); catalogued as rs147103435, COSV51901025; called by muse, mutect2, varscan2
- CADPS | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs149527472; called by muse, mutect2, varscan2
- CADPS | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1395502026; called by muse, mutect2, varscan2
- CALCB | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 59/298 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs369737294; called by muse, mutect2, varscan2
- CALCR | c.685C>T p.R229* (on ENST00000649521 / NM_001164737.2; = p.R213* on NM_001742.4) | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as rs376632735; called by mutect2, varscan2
- CALCRL | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101131018; called by muse, mutect2, varscan2
- CALHM1 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.022); catalogued as COSV61707025; called by muse, mutect2, varscan2
- CALHM2 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs759757943, COSV53296234; called by muse, mutect2, varscan2
- CAMK2A | c.1186C>T p.R396* (on ENST00000348628 / NM_171825.2; = p.R407* on NM_015981.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/201 reads (13%) | catalogued as rs753708011, CM142905; called by muse, mutect2, varscan2
- CAMKMT | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs765409677; called by muse, mutect2, varscan2
- CAMSAP1 | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs763497335, COSV56725184; called by mutect2, varscan2
- CAMSAP2 | c.2425A>G p.I809V (on ENST00000236925 / NM_001297707.2; = p.I798V on NM_203459.3) | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1252646355; called by muse, mutect2
- CAMSAP2 | c.3793C>T p.R1265* (on ENST00000236925 / NM_001297707.2; = p.R1254* on NM_203459.3) | Nonsense Mutation (SNP) | VAF 58/180 reads (32%) | catalogued as COSV52666995; called by muse, mutect2, varscan2
- CAMSAP3 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 22/195 reads (11%) | catalogued as rs772674054; called by muse, mutect2, varscan2
- CAMTA1 | c.2107G>C p.V703L | Missense Mutation (SNP) | VAF 74/312 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.006); catalogued as rs781250966, COSV100351866; called by muse, mutect2, varscan2
- CAMTA2 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.988); catalogued as rs1463860330, COSV61835053; called by muse, mutect2, varscan2
- CAP2 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57731888, COSV57735984; called by muse, mutect2, varscan2
- CAPN12 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs756044421, COSV61015022; called by muse, mutect2, varscan2
- CAPN2 | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1211814217; called by muse, mutect2, varscan2
- CAPRIN2 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1279171030, COSV51831414, COSV51832203; called by muse, mutect2, varscan2
- CAPZA3 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs200098261; called by muse, mutect2, varscan2
- CARD11 | c.799C>A p.L267M | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.719); catalogued as COSV67803167; called by muse, mutect2, varscan2
- CARD18 | c.38T>C p.F13S | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73233253; called by muse, mutect2, varscan2
- CARTPT | c.162C>T p.I54= | Splice Region (SNP) | VAF 154/534 reads (29%) | catalogued as COSV57116032; called by muse, mutect2, varscan2
- CASP14 | c.475A>G p.I159V | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.405); catalogued as rs1296353883; called by muse, varscan2
- CASP8 | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51854266; called by muse, varscan2
- CASP8AP2 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.051); catalogued as rs758643574, COSV52746227; called by mutect2, varscan2
- CASZ1 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 69/280 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1298788825; called by muse, mutect2, varscan2
- CBFA2T3 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.026); catalogued as rs899943902; called by mutect2, varscan2
- CBL | c.2536C>T p.P846S | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs745842672; called by muse, mutect2, varscan2
- CBLN2 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54050478, COSV54052636; called by muse, mutect2, varscan2
- CBWD6 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 21/133 reads (16%) | catalogued as rs1368646032; called by muse, mutect2, varscan2
- CBY2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60118177; called by muse, mutect2
- CBY3 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 60/181 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1426948110; called by muse, mutect2, varscan2
- CC2D1A | c.2788G>A p.D930N | Missense Mutation (SNP) | VAF 39/358 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV54308880; called by muse, mutect2, varscan2
- CC2D2A | c.3670C>T p.R1224W | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs369648324; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC105 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs370743090; called by muse, mutect2, varscan2
- CCDC105 | c.1316C>T p.T439M | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV52964182; called by muse, mutect2
- CCDC130 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs202065091, COSV55583483; called by muse, varscan2
- CCDC138 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54565240; called by muse, mutect2, varscan2
- CCDC14 | c.359G>A p.R120K (on ENST00000488653; = p.R72K on NM_022757.5) | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as rs1302413297; called by muse, mutect2
- CCDC141 | c.3805C>T p.P1269S | Missense Mutation (SNP) | VAF 118/607 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as rs770340923; called by muse, varscan2
- CCDC144A | c.3814G>A p.E1272K | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.946); catalogued as rs56371417, COSV100138414; called by muse, mutect2, varscan2
- CCDC150 | c.2911C>T p.R971W | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as rs181244179; called by mutect2, varscan2
- CCDC168 | c.20459C>A p.P6820H | Missense Mutation (SNP) | VAF 49/265 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100487755; called by muse, mutect2, varscan2
- CCDC168 | c.15500C>T p.S5167L | Missense Mutation (SNP) | VAF 53/384 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs555882008, COSV59420393; called by muse, mutect2, varscan2
- CCDC168 | c.11448G>T p.K3816N | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs1480172220, COSV59423601; called by muse, mutect2, varscan2
- CCDC168 | c.10681G>T p.E3561* | Nonsense Mutation (SNP) | VAF 74/324 reads (23%) | catalogued as COSV59425523; called by muse, mutect2, varscan2
- CCDC173 | c.836A>C p.K279T | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); catalogued as rs757806315, COSV71428572; called by muse, mutect2, varscan2
- CCDC178 | c.1366C>T p.L456F | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs375342485; called by muse, varscan2
- CCDC178 | c.1328C>A p.S443Y | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV55771352; called by muse, varscan2
- CCDC18 | c.1427A>G p.D476G | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as rs746095937; called by muse, mutect2, varscan2
- CCDC180 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs768434399, COSV63830653, COSV63831225; called by muse, mutect2, varscan2
- CCDC190 | c.485C>A p.S162Y | Missense Mutation (SNP) | VAF 88/334 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs1312017712, COSV63363236; called by muse, mutect2, varscan2
- CCDC191 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1295564781; called by muse, mutect2, varscan2
- CCDC25 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1188357550, COSV62959324; called by muse, mutect2
- CCDC30 | c.917G>A p.R306Q (on ENST00000340612; = p.R263Q on NM_001080850.3) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.884); catalogued as rs759851719, COSV59607235; called by muse, mutect2, varscan2
- CCDC30 | c.1429A>G p.T477A (on ENST00000340612; = p.T434A on NM_001080850.3) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV59609421; called by muse, mutect2, varscan2
- CCDC33 | c.31G>T p.D11Y | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.465); catalogued as COSV58351742; called by muse, mutect2, varscan2
- CCDC54 | c.868A>C p.T290P | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV53758044; called by muse, mutect2
- CCDC63 | c.630G>T p.M210I | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV57527081; called by muse, mutect2, varscan2
- CCDC65 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV104386013; called by muse, mutect2, varscan2
- CCDC7 | c.2977G>A p.D993N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as rs572731029; called by mutect2, varscan2
- CCDC73 | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770945256; called by muse, mutect2, varscan2
- CCDC73 | c.743A>C p.K248T | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV58795729; called by muse, mutect2, varscan2
- CCDC73 | c.642G>T p.K214N | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100068109; called by muse, mutect2, varscan2
- CCDC8 | c.731G>A p.S244N | Missense Mutation (SNP) | VAF 79/337 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.086); catalogued as rs751627096; called by muse, mutect2, varscan2
- CCDC87 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 83/312 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1163029104; called by muse, varscan2
- CCDC88C | c.5146C>T p.P1716S | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.033); catalogued as rs1419251714; called by muse, mutect2, varscan2
- CCDC88C | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.312); catalogued as rs368499200; called by muse, mutect2, varscan2
- CCL16 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs199602184; called by muse, mutect2, varscan2
- CCN2 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 36/327 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63466439; called by muse, mutect2, varscan2
- CCNB3 | c.3239G>A p.G1080D | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.412); catalogued as rs910410150; called by muse, mutect2
- CCNDBP1 | c.634A>G p.N212D | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs867909765; called by muse, mutect2, varscan2
- CCNL1 | c.437T>C p.I146T | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as rs1328710506; called by muse, mutect2, varscan2
- CCNL2 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101275711; called by muse, mutect2, varscan2
- CCP110 | c.761G>T p.R254I | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV66817501; called by muse, mutect2
- CCR2 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.2); catalogued as rs1355689842; called by muse, mutect2, varscan2
- CCR9 | c.974G>A p.R325H (on ENST00000357632 / NM_031200.3; = p.R313H on NM_006641.4) | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1475948592, COSV62940257; called by muse, mutect2, varscan2
- CCSER1 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1310425221; called by muse, mutect2, varscan2
- CCSER1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs745548077, COSV100390706, COSV61437396; called by muse, mutect2, varscan2
- CCSER1 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764157620; called by muse, mutect2, varscan2
- CCT6A | c.1004C>A p.S335Y | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as COSV99303764; called by muse, mutect2, varscan2
- CCZ1B | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as rs764721779, COSV57436035; called by mutect2, varscan2
- CCZ1B | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs543550013; called by muse, mutect2, varscan2
- CD180 | c.746C>A p.S249Y | Missense Mutation (SNP) | VAF 49/326 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs74683094, COSV56519311; called by muse, mutect2, varscan2
- CD200R1L | c.811C>A p.L271I | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as rs1351213746, COSV68003930, COSV68004269; called by muse, mutect2
- CD2AP | c.1611dup p.D538Rfs*20 | Frame Shift Ins (INS) | VAF 12/104 reads (12%) | catalogued as rs779712608; called by mutect2, varscan2
- CD300A | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.249); catalogued as COSV60409469; called by muse, mutect2, varscan2
- CD300LG | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 42/403 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs267604895; called by muse, mutect2, varscan2
- CD33 | c.365G>T p.R122I | Missense Mutation (SNP) | VAF 35/303 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV51803585; called by muse, mutect2, varscan2
- CD34 | c.323C>A p.S108Y | Missense Mutation (SNP) | VAF 23/349 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100178242, COSV60413996; called by muse, mutect2
- CD36 | c.500C>A p.S167Y | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV99987982; called by muse, mutect2, varscan2
- CD55 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.039); catalogued as rs752481959, COSV58577063, COSV58577291; called by muse, mutect2, varscan2
- CD58 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 23/145 reads (16%) | catalogued as COSV65664667, COSV65665124; called by muse, mutect2, varscan2
- CD6 | c.1972G>T p.D658Y | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV57843547; called by muse, mutect2, varscan2
- CD70 | c.401C>A p.S134Y | Missense Mutation (SNP) | VAF 57/356 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as COSV55565513; called by muse, mutect2, varscan2
- CDC14B | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 35/165 reads (21%) | catalogued as COSV55790619; called by mutect2, varscan2
- CDC42EP4 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 122/463 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.424); catalogued as rs1443916047; called by muse, mutect2, varscan2
- CDC45 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.107); catalogued as rs764940993, COSV54245341; called by muse, mutect2, varscan2
- CDCA2 | c.2818G>T p.E940* | Nonsense Mutation (SNP) | VAF 14/130 reads (11%) | catalogued as COSV57944091; called by muse, varscan2
- CDCP2 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs781568424; called by muse, mutect2, varscan2
- CDH1 | c.1109A>G p.D370G | Missense Mutation (SNP) | VAF 42/320 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55740119, COSV55741968; called by muse, mutect2, varscan2
- CDH10 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs1162170191; called by muse, varscan2
- CDH11 | c.2230G>A p.G744S | Missense Mutation (SNP) | VAF 56/408 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs374889086, COSV51753347, COSV51767545; called by muse, mutect2, varscan2
- CDH12 | c.2358G>T p.E786D | Missense Mutation (SNP) | VAF 55/270 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV66388978; called by muse, mutect2, varscan2
- CDH12 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759364590; called by mutect2, varscan2
- CDH13 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.182); catalogued as rs201622114; called by muse, mutect2, varscan2
- CDH24 | c.153C>A p.F51L | Missense Mutation (SNP) | VAF 65/277 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as COSV52974248, COSV52977706; called by muse, mutect2, varscan2
- CDH5 | c.2324G>A p.G775D | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100439204; called by muse, mutect2, varscan2
- CDH8 | c.241C>A p.L81I | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV54882948; called by muse, varscan2
- CDH9 | c.137A>G p.K46R | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1224180833; called by muse, mutect2, varscan2
- CDHR1 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 93/402 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs201649854; called by muse, mutect2, varscan2
- CDK12 | c.3382G>A p.D1128N | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.825); catalogued as rs1567782885, COSV71002400; called by muse, mutect2, varscan2
- CDK19 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0.34); catalogued as rs953895657; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 44/324 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs746203438, COSV62573211, COSV62573947; called by muse, mutect2
- CDKN1A | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779063779; called by muse, mutect2, varscan2
- CDKN2C | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs974925210; called by muse, mutect2
- CDON | c.3344G>A p.R1115Q | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.564); catalogued as rs762571384; called by muse, mutect2, varscan2
- CDPF1 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 38/363 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs763187970, COSV53080557; called by mutect2, varscan2
- CDRT1 | c.1222C>A p.L408I | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1297615725, COSV99887669; called by muse, mutect2
- CDS1 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV99880356; called by muse, mutect2, varscan2
- CDS1 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs776915359, COSV55690760; called by muse, mutect2, varscan2
- CDSN | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 118/434 reads (27%) | catalogued as rs781189010; called by muse, mutect2, varscan2
- CEBPZOS | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs771263212, COSV99304947; called by muse, mutect2, varscan2
- CEL | c.1089G>A p.T363= (on ENST00000673714; = p.T360= on NM_001807.6) | Splice Region (SNP) | VAF 69/558 reads (12%) | catalogued as rs767182910; called by muse, mutect2, varscan2
- CELF4 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV58467413; called by muse, mutect2, varscan2
- CELSR1 | c.6257C>T p.A2086V | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs775021743; called by muse, mutect2, varscan2
- CELSR2 | c.4198C>T p.R1400C | Missense Mutation (SNP) | VAF 50/225 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs374621786; called by muse, mutect2, varscan2
- CELSR3 | c.6989G>A p.R2330H | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.971); catalogued as rs556627156, COSV51145785; called by mutect2, varscan2
- CENPBD1 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 93/347 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV99240497; called by muse, mutect2, varscan2
- CENPF | c.5312A>C p.N1771T | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.03); catalogued as COSV100871902; called by muse, mutect2, varscan2
- CENPJ | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs758150747; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CENPJ | c.827A>C p.K276T | Missense Mutation (SNP) | VAF 48/285 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV101121545; called by muse, mutect2, varscan2
- CENPU | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as rs372424575; called by muse, mutect2, varscan2
- CEP120 | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759270074; called by muse, mutect2, varscan2
- CEP135 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs766575411; called by muse, varscan2
- CEP162 | c.3847C>T p.R1283* | Nonsense Mutation (SNP) | VAF 19/66 reads (29%) | catalogued as rs1191200730, COSV100002406; called by muse, mutect2, varscan2
- CEP164 | c.4082G>A p.R1361H | Missense Mutation (SNP) | VAF 83/302 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as rs148987415; called by muse, mutect2, varscan2
- CEP170 | c.2725C>T p.R909C | Missense Mutation (SNP) | VAF 81/250 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747765378, COSV60507867; called by muse, mutect2, varscan2
- CEP170B | c.1687G>A p.D563N (on ENST00000453495; = p.D492N on NM_015005.3) | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs868330788; called by muse, mutect2, varscan2
- CEP19 | c.403A>C p.N135H | Missense Mutation (SNP) | VAF 88/224 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV56361370; called by muse, varscan2
- CEP192 | c.6122G>A p.R2041Q | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs762016805; called by muse, mutect2, varscan2
- CEP250 | c.3134G>A p.R1045Q | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs763406705, COSV61168241; called by mutect2, varscan2
- CEP290 | c.3970A>C p.K1324Q | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.793); catalogued as COSV58356726; called by muse, mutect2, varscan2
- CEP350 | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 12/118 reads (10%) | catalogued as rs138545141; called by mutect2, varscan2
- CEP350 | c.5581C>T p.R1861W | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1296558578, COSV62607883; called by muse, mutect2, varscan2
- CEP63 | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 47/186 reads (25%) | catalogued as COSV59674302; called by muse, mutect2, varscan2
- CEP95 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV101616289, COSV101616340; called by muse, mutect2, varscan2
- CERK | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 51/215 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs144409797; called by muse, mutect2, varscan2
- CERS2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 83/207 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1355471060; called by muse, mutect2, varscan2
- CERS3 | c.894C>A p.F298L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as COSV52564980; called by muse, mutect2, varscan2
- CERS3 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752230253, COSV52567747; called by muse, mutect2, varscan2
- CFAP251 | c.2234G>A p.R745Q | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs759115110, COSV56608100; called by muse, varscan2
- CFAP251 | c.2911G>A p.D971N | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as rs1318095723, COSV56611223, COSV56612298; called by muse, mutect2
- CFAP300 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as rs140641107; called by muse, mutect2, varscan2
- CFAP43 | c.1058C>A p.S353Y | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53378024; called by muse, mutect2, varscan2
- CFAP46 | c.8012C>T p.A2671V | Missense Mutation (SNP) | VAF 63/280 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs199869831, COSV54148585; called by muse, mutect2, varscan2
- CFAP46 | c.4868C>T p.S1623L | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs1018417455; called by muse, mutect2, varscan2
- CFAP47 | c.1893G>T p.K631N | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as rs747060647, COSV52882246, COSV52887910; called by muse, mutect2, varscan2
- CFAP52 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as rs766919743; called by mutect2, varscan2
- CFAP57 | c.2671C>T p.R891W | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs746742789, COSV100993812; called by muse, mutect2, varscan2
- CFAP58 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 55/218 reads (25%) | catalogued as COSV57211635; called by muse, mutect2, varscan2
- CFAP58 | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as rs143080879; called by muse, mutect2, varscan2
- CFAP65 | c.2812G>A p.E938K | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs371538009; called by mutect2, varscan2
- CFAP65 | c.2302G>A p.A768T | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs765097178; called by muse, mutect2, varscan2
- CFAP91 | c.1367A>C p.K456T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); catalogued as COSV56340848; called by muse, mutect2, varscan2
- CFTR | c.2104C>A p.L702I | Missense Mutation (SNP) | VAF 82/264 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.02); catalogued as COSV99136013; called by muse, varscan2
- CGN | c.3250G>T p.E1084* | Nonsense Mutation (SNP) | VAF 17/161 reads (11%) | catalogued as COSV104376545, COSV54968167; called by mutect2, varscan2
- CGNL1 | c.1019G>T p.G340V | Missense Mutation (SNP) | VAF 55/344 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55571064; called by muse, mutect2, varscan2
- CHAT | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs915451905; called by muse, mutect2, varscan2
- CHD1 | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV52336710; called by muse, mutect2
- CHD1L | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1344772841, COSV63613424; called by muse, mutect2, varscan2
- CHD4 | c.2306C>T p.A769V (on ENST00000357008 / NM_001363606.2; = p.A782V on NM_001273.5) | Missense Mutation (SNP) | VAF 76/287 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as COSV58906653; called by muse, mutect2, varscan2
- CHD5 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 86/306 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.042); catalogued as rs542999319; called by mutect2, varscan2
- CHD7 | c.2552G>T p.R851I | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV71107551, COSV71111239; called by muse, mutect2, varscan2
- CHD8 | c.4216C>T p.R1406C (on ENST00000646647 / NM_001170629.2; = p.R1127C on NM_020920.4) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs774260771, COSV100783889; called by muse, mutect2, varscan2
- CHD9 | c.4631G>A p.R1544Q | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1212023003, COSV99528775; called by muse, mutect2, varscan2
- CHGB | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 26/204 reads (13%) | catalogued as rs891947037; called by muse, varscan2
- CHKB | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 140/579 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs200919604, COSV56414909; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHL1 | c.925C>T p.R309C (on ENST00000397491 / NM_001253387.1; = p.R325C on NM_006614.4) | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as rs769936753; called by muse, mutect2, varscan2
- CHMP5 | c.174G>T p.K58N | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99794613; called by muse, mutect2
- CHRM2 | c.742A>G p.M248V | Missense Mutation (SNP) | VAF 110/511 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1390053717; called by muse, varscan2
- CHRM3 | c.147C>A p.F49L | Missense Mutation (SNP) | VAF 88/291 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs756421149, COSV55079713; called by muse, mutect2, varscan2
- CHRNA1 | c.760C>T p.R254C (on ENST00000261007 / NM_001039523.3; = p.R229C on NM_000079.4) | Missense Mutation (SNP) | VAF 59/630 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs745355427, CM132621, COSV53681813; called by muse, mutect2
- CHRNA4 | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 27/274 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs375524982, CM1212665, COSV64719127; called by muse, mutect2, varscan2
- CHRNA4 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761317422, COSV64718151; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST15 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs199887555, COSV60560141, COSV60560330; called by muse, mutect2, varscan2
- CHST9 | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 37/255 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as COSV52433817; called by muse, mutect2, varscan2
- CHSY3 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59290344; called by muse, mutect2
- CIART | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs782348606, COSV51746083; called by muse, mutect2, varscan2
- CILP | c.3377G>A p.R1126H | Missense Mutation (SNP) | VAF 66/306 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs201994328, COSV56024942; called by muse, mutect2, varscan2
- CILP | c.2251C>T p.R751W | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775403820, COSV56025529, COSV99973176; called by muse, mutect2, varscan2
- CILP2 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.176); catalogued as rs774293541; called by muse, mutect2, varscan2
- CIR1 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as rs769148227, COSV59596422; called by muse, mutect2, varscan2
- CIT | c.2923G>A p.D975N | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs1421433139, COSV55869918; called by muse, mutect2, varscan2
- CKAP4 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 63/276 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376479872; called by muse, mutect2, varscan2
- CKMT1B | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs757398292; called by muse, mutect2, varscan2
- CLASP1 | c.2302C>T p.R768W | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs765905351, COSV55315928; called by muse, mutect2, varscan2
- CLASP1 | c.860C>A p.S287Y | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.309); catalogued as COSV55322082; called by muse, mutect2, varscan2
- CLASP2 | c.2616G>T p.Q872H | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.888); catalogued as COSV56285932; called by muse, mutect2, varscan2
- CLCF1 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 35/320 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs104894203, CM066008, COSV100425603; called by muse, mutect2, varscan2
- CLCN4 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs184474252, COSV66466815; called by muse, mutect2, varscan2
- CLCN4 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66464930; called by muse, mutect2, varscan2
- CLCN7 | c.2402C>T p.S801L | Missense Mutation (SNP) | VAF 40/343 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as rs184833329; called by muse, mutect2, varscan2
- CLCNKA | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 141/652 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs771717536, COSV58894616; called by muse, mutect2, varscan2
- CLDN9 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as rs754832732, COSV60910384; called by mutect2, varscan2
- CLEC12B | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as rs753661436, COSV58863501; called by muse, mutect2, varscan2
- CLEC4A | c.284del p.N95Ifs*49 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | catalogued as rs760557093; called by mutect2, varscan2
10,935 further variants in this file (7,375 protein-altering or splice-affecting, 2,172 silent, 1,388 other) are not listed here.
